Somatic mutation profile of tumor specimen TCGA-34-2609-01A (aliquot TCGA-34-2609-01A-01D-1522-08) from TCGA case TCGA-34-2609, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 81.8 years (29,871 days).
Specimen TCGA-34-2609-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6452210-2b23-4f1b-8d06-4a457401f252.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-2609-11A (Solid Tissue Normal), aliquot TCGA-34-2609-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f00c495-6288-4b20-94f2-49f793dcf664

The open-access MAF lists 264 somatic variants for this specimen: 203 protein-altering or splice-affecting, 53 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 53, Nonsense Mutation 9, Splice Site 6, Frame Shift Del 5, RNA 3, Intron 2, Frame Shift Ins 2, 3'UTR 1, In Frame Ins 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.457+2T>A p.X153_splice | Splice Site (SNP) | VAF 14/37 reads (38%) | hotspot (GDC flag); catalogued as COSV58683976, COSV58692776; called by muse, mutect2, varscan2
- TP53 | c.193A>T p.R65* | Nonsense Mutation (SNP) | VAF 127/282 reads (45%) | catalogued as rs1555526721, COSV52689560; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC5 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99656687; called by muse, mutect2, varscan2
- ABHD2 | c.411C>A p.H137Q | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as COSV100756240; called by muse, mutect2, varscan2
- ACE | c.639A>C p.E213D | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV99326754; called by muse, mutect2, varscan2
- ACE | c.3625C>T p.R1209C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.352); catalogued as rs1353694784, COSV99326758; called by muse, mutect2, varscan2
- ADAM15 | c.763G>C p.V255L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99664901; called by muse, mutect2, varscan2
- ADAM23 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as COSV100007243; called by muse, mutect2, varscan2
- ADAMTS20 | c.4802C>A p.A1601E | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV101239127; called by muse, mutect2
- ADGRA2 | c.1422G>C p.L474F | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as COSV100177783, COSV59444725; called by muse, mutect2
- ADGRL3 | c.272C>G p.A91G (on ENST00000506720 / NM_001322402.2; = p.A23G on NM_015236.6) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101546983; called by muse, varscan2
- AMTN | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100219672, COSV59489048; called by muse, mutect2, varscan2
- AMZ1 | c.740T>A p.F247Y | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV100406306; called by muse, mutect2, varscan2
- APCS | c.49G>C p.A17P | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV54819122, COSV99661251; called by muse, mutect2, varscan2
- ARRDC4 | c.500A>G p.D167G | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV99164343; called by muse, mutect2, varscan2
- ASPM | c.5687G>A p.R1896K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.262); catalogued as COSV54128785; called by muse, mutect2, varscan2
- ATG4C | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100508017; called by muse, mutect2, varscan2
- ATP13A4 | c.1919C>T p.P640L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99794324; called by muse, mutect2
- BDKRB2 | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100021038; called by muse, mutect2, varscan2
- BMPER | c.1505G>A p.G502E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99779353; called by mutect2, varscan2
- BTBD8 | c.1010A>T p.D337V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.366); catalogued as COSV100730203; called by muse, mutect2
- C12orf42 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs1222458305, COSV100172030; called by muse, mutect2, varscan2
- CA6 | c.482T>C p.V161A | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101077466; called by muse, mutect2, varscan2
- CAB39 | c.385A>G p.M129V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99299782; called by muse, mutect2, varscan2
- CALD1 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100724139, COSV100724648; called by muse, mutect2, varscan2
- CAPN9 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99680226; called by muse, mutect2, varscan2
- CD163L1 | c.1024A>T p.R342* | Nonsense Mutation (SNP) | VAF 33/101 reads (33%) | catalogued as rs143956577; called by muse, mutect2, varscan2
- CDH10 | c.2209G>T p.A737S | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52573112, COSV52584409; called by muse, mutect2, varscan2
- CDH10 | c.1988G>T p.G663V | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52580048; called by muse, mutect2, varscan2
- CDH10 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050899; called by muse, mutect2, varscan2
- CDH18 | c.2030G>T p.R677M | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV56900908, COSV56928101; called by muse, mutect2, varscan2
- CFAP57 | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100763999; called by muse, mutect2, varscan2
- CLHC1 | c.1434G>T p.Q478H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV101284868; called by muse, mutect2, varscan2
- CNTNAP4 | c.3114C>G p.S1038R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV100270519, COSV56679445; called by muse, mutect2, varscan2
- COG6 | c.377A>T p.K126M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100742761; called by muse, mutect2, varscan2
- CPM | c.1036A>G p.N346D | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.151); catalogued as COSV100615012; called by muse, mutect2, varscan2
- CSMD3 | c.9956T>A p.F3319Y (on ENST00000297405 / NM_001363185.1; = p.F3150Y on NM_052900.3) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99830664; called by muse, mutect2, varscan2
- CST9 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as rs770383370, COSV100980472, COSV100980502; called by mutect2, varscan2
- DGKI | c.903G>T p.M301I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV99933430; called by muse, mutect2, varscan2
- DHCR7 | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV100831852; called by muse, mutect2, varscan2
- DNAH8 | c.12026A>G p.Q4009R | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100544283; called by muse, mutect2
- DNAJC8 | c.665G>T p.S222I | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99746176; called by muse, mutect2, varscan2
- DPPA4 | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.285); catalogued as COSV100169357; called by muse, mutect2, varscan2
- DROSHA | c.1550G>T p.R517L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV100757413, COSV100757561; called by muse, mutect2, varscan2
- EBF2 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV101282137; called by muse, mutect2, varscan2
- EPS8L3 | c.1091G>T p.G364V | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV100719693; called by muse, mutect2, varscan2
- ERN2 | c.2572C>A p.H858N | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99037830; called by muse, mutect2
- ESYT1 | c.3299A>G p.D1100G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99919874; called by muse, mutect2, varscan2
- FAM217A | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV99212711; called by muse, mutect2, varscan2
- FANCL | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99287415; called by muse, mutect2, varscan2
- FAT3 | c.2978G>T p.R993L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs539020470, COSV53072565; called by muse, mutect2
- FOXJ1 | c.260C>A p.T87K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99486860; called by muse, mutect2, varscan2
- FRMPD4 | c.3148C>A p.Q1050K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.029); catalogued as COSV101042595; called by muse, mutect2, varscan2
- FUS | c.1484G>T p.R495L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as CD1110975, COSV99568499; called by muse, mutect2, varscan2
- GALNT6 | c.686A>T p.E229V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100695380; called by muse, mutect2, varscan2
- GAP43 | c.56A>T p.K19M | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100525458; called by muse, mutect2, varscan2
- GLP2R | c.1489C>A p.L497I | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV52329540, COSV99301861; called by muse, mutect2, varscan2
- GLRA3 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as rs765420954, COSV99927339; called by muse, mutect2, varscan2
- GRIK2 | c.2306C>G p.P769R | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100024821, COSV59738132; called by muse, mutect2, varscan2
- GRM8 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | catalogued as COSV100281060; called by muse, mutect2
- GSTA3 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV99274493; called by muse, mutect2, varscan2
- HCAR1 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100811556; called by muse, mutect2, varscan2
- HCN1 | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1219412264, COSV100299639; called by muse, mutect2, varscan2
- HCN3 | c.1623G>T p.M541I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100712866; called by muse, mutect2, varscan2
- HERC1 | c.5119C>G p.Q1707E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.9); catalogued as COSV101496493; called by muse, mutect2
- HLA-DRB5 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100894442; called by muse, varscan2
- HTR1A | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.942); catalogued as rs1357859963, COSV100109324, COSV60500024; called by muse, mutect2, varscan2
- HYAL2 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99222693; called by muse, mutect2, varscan2
- IL17F | c.214C>A p.R72S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.022); catalogued as COSV100277163, COSV60234235; called by muse, mutect2, varscan2
- INTS13 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.757); catalogued as COSV99677274; called by muse, mutect2, varscan2
- ITPR1 | c.1703G>T p.R568M (on ENST00000354582; = p.R553M on NM_002222.7) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100230622; called by muse, mutect2, varscan2
- ITPR1 | c.1704G>T p.R568S (on ENST00000354582; = p.R553S on NM_002222.7) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100230623; called by muse, mutect2, varscan2
- ITPR2 | c.5488A>G p.I1830V | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs756645126, COSV101189925; called by muse, mutect2
- KDM5B | c.2879G>A p.R960Q | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1391895463, COSV52507201, COSV99350192; called by muse, mutect2
- KHDRBS2 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV55486054, COSV99832646; called by muse, mutect2
- KIF5A | c.1413C>A p.S471R | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV54058175; called by muse, mutect2
- KIR2DL1 | c.401A>G p.Q134R | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV99382951, COSV99383651; called by muse, mutect2, varscan2
- KIR2DL4 | c.1097C>A p.T366N (on ENST00000396284; = p.T292N on NM_001080770.2) | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV100428483; called by muse, mutect2, varscan2
- KMT2D | c.10030G>T p.A3344S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV99979786; called by muse, varscan2
- LAMA2 | c.4670G>T p.C1557F | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101370334; called by muse, mutect2, varscan2
- LCE2B | c.274T>G p.C92G | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated, low confidence (0.54); PolyPhen possibly damaging (0.479); catalogued as COSV100909295; called by muse, mutect2, varscan2
- LHCGR | c.643A>C p.N215H | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV99683467; called by muse, mutect2, varscan2
- LIG1 | c.919C>G p.R307G | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV99618753; called by muse, mutect2, varscan2
- LNPEP | c.2362G>T p.A788S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV99183510, COSV99183540; called by muse, mutect2, varscan2
- LRRC66 | c.1274T>C p.F425S | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100602911; called by muse, varscan2
- LRRC66 | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.453); catalogued as COSV100602912; called by muse, varscan2
- MAML1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 34/83 reads (41%) | catalogued as COSV99483034; called by muse, mutect2, varscan2
- MAP9 | c.482-1G>C p.X161_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100250837; called by muse, mutect2
- MC3R | c.809C>G p.T270S | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV99710523; called by muse, mutect2, varscan2
- MYBPC1 | c.943C>G p.Q315E (on ENST00000550270 / NM_206820.2; = p.Q340E on NM_002465.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV100637737, COSV100637879; called by muse, mutect2, varscan2
- MYBPC2 | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100731740; called by muse, mutect2, varscan2
- MYF5 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 30/139 reads (22%) | catalogued as rs370171499, COSV57356172; called by muse, mutect2, varscan2
- MYH1 | c.898C>G p.L300V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV99875486; called by muse, mutect2, varscan2
- MYO1F | c.2270G>C p.G757A | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as COSV100596548; called by muse, mutect2
- NAV3 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.637); catalogued as COSV99889263; called by muse, mutect2, varscan2
- NFKB2 | c.1106G>C p.G369A | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99192382; called by muse, mutect2, varscan2
- NFYB | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV99527150; called by muse, mutect2, varscan2
- NID2 | c.133dup p.D45Gfs*54 | Frame Shift Ins (INS) | VAF 11/60 reads (18%) | catalogued as rs1566780400; called by mutect2, pindel, varscan2
- NRAP | c.2449G>T p.A817S (on ENST00000359988 / NM_001322945.2; = p.A782S on NM_006175.4) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV100748376; called by muse, mutect2, varscan2
- NRG3 | c.612C>A p.S204R | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); catalogued as COSV64564089; called by muse, mutect2, varscan2
- OR10AG1 | c.151T>A p.Y51N | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100400031; called by muse, mutect2, varscan2
- OR10H5 | c.157C>A p.R53S | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as rs766738019, COSV100454683, COSV58279306; called by muse, mutect2
- OR4B1 | c.902G>A p.S301N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100535554; called by muse, mutect2
- OR4P4 | c.746T>C p.F249S | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100111663; called by muse, mutect2
- OR52A5 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100263376, COSV56614457; called by muse, mutect2, varscan2
- OR5L1 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); catalogued as rs61998198, COSV100450006, COSV61733363; called by muse, mutect2, varscan2
- OR6C65 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV101110180; called by muse, mutect2, varscan2
- OR8J3 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100040734, COSV100040849; called by muse, mutect2, varscan2
- ORC5 | c.527T>A p.V176D | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV99856870; called by muse, mutect2
- OSBPL6 | c.2751G>A p.W917* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV99507099; called by muse, mutect2, varscan2
- PAN3 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.748); catalogued as rs765586023, COSV56701201; called by muse, mutect2, varscan2
- PCDH11X | c.743T>A p.V248D | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV100010680; called by muse, mutect2, varscan2
- PCDH15 | c.3506C>A p.T1169N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.898); catalogued as COSV100218550; called by muse, mutect2, varscan2
- PCDH17 | c.2410C>A p.L804M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100931552; called by muse, varscan2
- PCDHA7 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 23/231 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV100971371; called by muse, mutect2
- PDE11A | c.140T>A p.I47K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as COSV100628636; called by muse, mutect2, varscan2
- PDGFA | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100627293; called by muse, mutect2, varscan2
- PITPNM1 | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.194); catalogued as COSV100711606; called by muse, mutect2, varscan2
- POLH | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV100947728; called by muse, mutect2, varscan2
- PPP4R1 | c.1940A>G p.Y647C (on ENST00000400556 / NM_001042388.3; = p.Y630C on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as rs910655495, COSV99553360; called by muse, mutect2, varscan2
- PPP4R4 | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV100175646; called by muse, mutect2
- PREPL | c.845G>C p.G282A | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.069); catalogued as COSV99576073; called by muse, mutect2, varscan2
- PRG3 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs766777813, COSV54664320; called by muse, mutect2, varscan2
- PRKG1 | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs761501836, COSV100907226; called by muse, mutect2, varscan2
- PRLR | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51493174, COSV99184297; called by muse, varscan2
- PRPF8 | c.4298A>C p.D1433A | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100517349; called by muse, mutect2, varscan2
- PRSS35 | c.585T>A p.S195R | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100864077; called by muse, mutect2
- PSG3 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 126/602 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV100548844; called by muse, varscan2
- PSG6 | c.357C>A p.Y119* | Nonsense Mutation (SNP) | VAF 76/556 reads (14%) | catalogued as COSV99413844; called by muse, mutect2, varscan2
- PTPRS | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.109); catalogued as COSV53619532, COSV99509985; called by muse, mutect2, varscan2
- PTPRT | c.1730C>T p.P577L | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100626438; called by muse, mutect2, varscan2
- PYY | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.018); catalogued as COSV100778921; called by muse, varscan2
- PZP | c.1285C>A p.H429N | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99737252; called by muse, mutect2, varscan2
- R3HDM1 | c.2654C>G p.P885R | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99926019; called by muse, mutect2, varscan2
- RAB11B | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV100033013; called by muse, mutect2
- RAD18 | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs757759853, COSV99368269; called by muse, mutect2, varscan2
- RAD21 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV99815016; called by muse, mutect2, varscan2
- RIMS2 | c.1932G>C p.W644C (on ENST00000666250 / NM_001348490.2; = p.W452C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51649822, COSV99166068; called by muse, mutect2, varscan2
- RP1 | c.3719C>A p.S1240Y | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV99606995; called by muse, mutect2, varscan2
- RPL6 | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV99176121; called by muse, mutect2, varscan2
- RYR1 | c.7793C>A p.A2598E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100615354, COSV62090807; called by mutect2, varscan2
- SALL1 | c.2490A>C p.E830D | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV99173113; called by muse, mutect2
- SATL1 | c.169A>G p.S57G (on ENST00000395409; = p.S244G on NM_001012980.2) | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100260755; called by muse, mutect2, varscan2
- SBK2 | c.948C>A p.S316R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV100705086, COSV100705273; called by muse, mutect2, varscan2
- SCFD2 | c.588G>C p.K196N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV101189330; called by muse, mutect2, varscan2
- SERINC4 | c.538+1G>T p.X180_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | catalogued as COSV99988343; called by muse, mutect2, varscan2
- SERINC4 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV99988346; called by muse, mutect2, varscan2
- SLC12A6 | c.2024G>A p.R675Q (on ENST00000354181 / NM_001365088.1; = p.R624Q on NM_005135.2) | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99271565; called by muse, mutect2
- SLC22A2 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs766277243; called by muse, mutect2, varscan2
- SLC24A5 | c.997T>A p.Y333N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV99981411; called by muse, mutect2, varscan2
- SLC26A5 | c.292+2T>G p.X98_splice | Splice Site (SNP) | VAF 31/109 reads (28%) | catalogued as COSV100099007; called by muse, mutect2, varscan2
- SMG6 | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as rs1567762456, COSV99558009; called by muse, mutect2, varscan2
- SNAPC4 | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1197589630, COSV100047079; called by muse, mutect2, varscan2
- SPAG6 | c.590A>T p.H197L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100510155; called by muse, mutect2, varscan2
- SPRR3 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV54881265, COSV99768492; called by muse, mutect2, varscan2
- STXBP5L | c.3206T>A p.F1069Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); catalogued as COSV99873243; called by muse, mutect2, varscan2
- TAAR2 | c.355T>A p.Y119N (on ENST00000367931 / NM_001033080.1; = p.Y74N on NM_014626.3) | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV99255595; called by muse, mutect2, varscan2
- TARS2 | c.779C>A p.S260* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | catalogued as COSV100945920; called by muse, mutect2
- TLL1 | c.1794G>T p.Q598H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV50313366, COSV50327864; called by mutect2, varscan2
- TMCC1 | c.1618C>G p.Q540E (on ENST00000393238 / NM_001349268.2; = p.Q216E on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61439493; called by muse, mutect2, varscan2
- TMEM200A | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV51649569, COSV99759006; called by muse, mutect2, varscan2
- TNFRSF13B | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs867307644, COSV99891411; called by muse, mutect2, varscan2
- TNFRSF25 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100556482; called by muse, mutect2, varscan2
- TNR | c.1334G>T p.W445L | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54881069; called by muse, mutect2, varscan2
- TRIM23 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99139927; called by muse, mutect2
- TRIM48 | c.571T>A p.L191I | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as COSV70162016; called by muse, mutect2, varscan2
- TRMT6 | c.1028T>C p.I343T | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99177546; called by muse, mutect2, varscan2
- TTC21B | c.3613G>A p.D1205N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99692133; called by muse, mutect2, varscan2
- TTLL9 | c.859G>C p.G287R | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100206571, COSV60593106; called by mutect2, varscan2
- TTN | c.56932G>T p.V18978F (on ENST00000591111; = p.V11554F on NM_003319.4) | Missense Mutation (SNP) | VAF 37/82 reads (45%) | PolyPhen benign (0.238); catalogued as rs1377163743, COSV100604401; called by muse, mutect2, varscan2
- UGGT2 | c.2201-1G>T p.X734_splice | Splice Site (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100948581; called by muse, mutect2, varscan2
- UGT3A1 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99954594; called by muse, mutect2, varscan2
- UNC5A | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56165312; called by muse, mutect2, varscan2
- VARS1 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV100989920; called by muse, mutect2
- VARS1 | c.1469T>C p.V490A | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100989921; called by muse, mutect2
- VNN2 | c.214-2A>T p.X72_splice | Splice Site (SNP) | VAF 16/74 reads (22%) | catalogued as COSV58472772; called by muse, mutect2, varscan2
- VPS13B | c.11371G>T p.A3791S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100661581; called by muse, mutect2, varscan2
- VRTN | c.979_980insT p.G327Vfs*27 | Frame Shift Ins (INS) | VAF 10/98 reads (10%) | catalogued as COSV99832194; called by mutect2, pindel, varscan2
- WARS1 | c.67G>C p.V23L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV100690118, COSV59925963; called by muse, mutect2, varscan2
- WNT3A | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs908046368, COSV52732415; called by muse, mutect2, varscan2
- XDH | c.2502G>T p.M834I | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs765724627, COSV101052149; called by muse, mutect2, varscan2
- XKR3 | c.848T>A p.F283Y | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100509201; called by muse, mutect2, varscan2
- ZBED6CL | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 80/248 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1382641688, COSV100550439; called by muse, mutect2, varscan2
- ZFHX4 | c.5849C>T p.T1950I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1223506129, COSV99260970; called by muse, mutect2, varscan2
- ZFP36 | c.304G>T p.A102S (on ENST00000594442; = p.A96S on NM_003407.5) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as COSV99953753; called by muse, mutect2, varscan2
- ZG16B | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66525832, COSV66525942; called by muse, mutect2, varscan2
- ZNF302 | c.1196A>G p.K399R (on ENST00000627982; = p.K320R on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1323709654, COSV101416462; called by muse, mutect2
- ZNF423 | c.193G>T p.D65Y (on ENST00000563137 / NM_001379286.1; = p.D57Y on NM_015069.4) | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.123); catalogued as COSV99280928; called by muse, mutect2, varscan2
- ZNF649 | c.683A>T p.H228L | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100030949; called by muse, mutect2, varscan2
- ZNF780A | c.593G>T p.C198F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100575041; called by muse, mutect2, varscan2
- ZSCAN2 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.65); catalogued as COSV100491460; called by muse, mutect2, varscan2
- CFHR4 | c.1622del p.T541Kfs*30 (on ENST00000367416 / NM_001201551.2; = p.T295Kfs*30 on NM_006684.5) | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by mutect2, pindel, varscan2
- FGFR2 | c.801_803dup p.T268dup | In Frame Ins (INS) | VAF 14/58 reads (24%) | called by mutect2, pindel, varscan2
- KDM6A | c.2580del p.E861Nfs*6 | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | called by mutect2, varscan2
- MYOM3 | c.3472del p.A1158Qfs*70 | Frame Shift Del (DEL) | VAF 33/121 reads (27%) | called by mutect2, pindel, varscan2
- NDUFS8 | c.217_225del p.S73_L75del | In Frame Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel
- NRXN3 | c.665G>T p.C222F | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PCDHA3 | c.1856_1857del p.R619Hfs*37 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | called by pindel, varscan2
- PRAMEF14 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SPIDR | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- SRCIN1 | c.2729G>T p.G910V (on ENST00000621492; = p.G876V on NM_025248.3) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WFDC3 | c.357G>A p.L119= | Splice Region (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- WWC3 | c.3081del p.Q1028Rfs*19 | Frame Shift Del (DEL) | VAF 5/9 reads (56%) | called by mutect2, varscan2
- ACAN | c.5277C>A p.S1759= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV100717683; called by muse, mutect2, varscan2
- AMPD3 | c.1140G>A p.R380= (on ENST00000396553 / NM_001025389.2; = p.R389= on NM_000480.3) | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV101158134; called by muse, mutect2, varscan2
- ANO7 | c.1152G>T p.L384= (on ENST00000274979; = p.L330= on NM_001370694.2) | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as COSV99237987; called by muse, mutect2, varscan2
- APOB | c.13563T>A p.I4521= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV51949873, COSV99264856; called by muse, mutect2
- ARMC4 | c.2895G>T p.V965= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100536579; called by muse, mutect2, varscan2
- B4GALNT2 | c.57C>G p.G19= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV100302504; called by muse, mutect2
- CBR1 | c.708G>C p.A236= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99289431; called by muse, mutect2, varscan2
- CCDC150 | c.567G>T p.S189= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV55873851, COSV55874197; called by muse, mutect2, varscan2
- CD1B | c.552C>T p.C184= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as rs1470701293, COSV100939202; called by muse, mutect2, varscan2
- CEBPD | c.708C>T p.R236= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99854696; called by muse, mutect2, varscan2
- CNTNAP2 | c.2241G>T p.A747= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100664824; called by muse, varscan2
- CUL3 | c.1113G>T p.A371= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100023961; called by muse, mutect2, varscan2
- CYB5D2 | c.669C>T p.T223= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as rs534144144, COSV100028914; called by muse, mutect2, varscan2
- DLGAP5 | c.606G>A p.S202= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs377000715; called by muse, mutect2, varscan2
- DNAH3 | c.10065G>T p.L3355= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as rs755332249, COSV54549037, COSV99766316; called by muse, mutect2, varscan2
- DOCK11 | c.4656C>T p.F1552= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as rs746053640, COSV99353473; called by muse, mutect2, varscan2
- ELAPOR2 | c.2751G>A p.K917= (on ENST00000450689 / NM_001142749.3; = p.K750= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 48/155 reads (31%) | catalogued as COSV99788566; called by muse, mutect2, varscan2
- EPHB1 | c.2457A>T p.S819= | Silent (SNP) | VAF 75/401 reads (19%) | catalogued as COSV101212964; called by muse, mutect2, varscan2
- F9 | c.1266C>G p.T422= | Silent (SNP) | VAF 41/62 reads (66%) | catalogued as COSV99496477; called by muse, mutect2, varscan2
- FLRT2 | c.1188G>A p.T396= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs200412416, COSV58143947; called by muse, mutect2, varscan2
- GRM1 | c.9G>T p.G3= | Silent (SNP) | VAF 48/248 reads (19%) | catalogued as COSV99265331; called by muse, varscan2
- IL1RAPL2 | c.534G>C p.V178= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100781097; called by muse, mutect2, varscan2
- IL21R | c.1530C>A p.P510= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV61972612; called by muse, mutect2, varscan2
- INTS8 | c.2427G>T p.V809= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100569220; called by muse, mutect2, varscan2
- ITIH6 | c.2301C>A p.I767= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV54492106, COSV99513120; called by muse, mutect2, varscan2
- KHDRBS2 | c.624T>A p.G208= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99832649; called by muse, mutect2
- KLHL28 | c.1422G>T p.V474= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100753056, COSV61888374; called by muse, mutect2, varscan2
- KMT2C | c.5199G>T p.S1733= | Silent (SNP) | VAF 92/248 reads (37%) | catalogued as COSV100070217, COSV51309675; called by muse, mutect2, varscan2
- LAP3 | c.948C>A p.I316= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV99884205; called by muse, mutect2, varscan2
- LRTM2 | c.1005C>T p.Y335= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs750674817, COSV54564397; called by muse, mutect2, varscan2
- LY6D | c.378C>A p.P126= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100009269, COSV56661027; called by muse, mutect2, varscan2
- NDNF | c.1704T>C p.C568= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV65633969; called by muse, mutect2
- NR1D2 | c.1200A>G p.E400= | Silent (SNP) | VAF 19/131 reads (15%) | catalogued as COSV100437363; called by muse, mutect2, varscan2
- OR13G1 | c.501G>T p.G167= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100687158; called by muse, mutect2, varscan2
- OR2M2 | c.735C>A p.L245= | Silent (SNP) | VAF 21/198 reads (11%) | catalogued as COSV100677213; called by muse, mutect2, varscan2
- OR4K5 | c.330G>A p.G110= | Silent (SNP) | VAF 17/279 reads (6%) | catalogued as rs747328075, COSV100262282; called by muse, mutect2
- OR4L1 | c.117G>T p.V39= | Silent (SNP) | VAF 97/183 reads (53%) | catalogued as COSV100235638; called by muse, mutect2, varscan2
- PABPC1L | c.609C>T p.D203= | Silent (SNP) | VAF 12/252 reads (5%) | catalogued as rs1227408363, COSV99407525; called by muse, mutect2
- PLCE1 | c.3747C>T p.S1249= | Silent (SNP) | VAF 28/167 reads (17%) | catalogued as rs530724888, COSV53368555; called by muse, mutect2, varscan2
- PRAMEF8 | c.936C>A p.L312= | Silent (SNP) | VAF 11/196 reads (6%) | called by muse, mutect2
- PTCHD1 | c.1005C>A p.V335= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV101037427; called by muse, mutect2, varscan2
- PTPN13 | c.792A>T p.G264= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100364510; called by muse, mutect2
- REXO1 | c.528G>T p.P176= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV50090557, COSV99402186; called by muse, mutect2, varscan2
- RGL1 | c.33G>T p.S11= (on ENST00000360851 / NM_001297672.2; = p.S46= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100486421, COSV58982544; called by muse, mutect2, varscan2
- SEC14L4 | c.831G>A p.Q277= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99742846; called by muse, mutect2, varscan2
- SEC31A | c.1158G>T p.P386= | Silent (SNP) | VAF 49/199 reads (25%) | catalogued as COSV100021751; called by muse, mutect2, varscan2
- SLC26A3 | c.528G>A p.V176= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100384977; called by muse, mutect2, varscan2
- SPAG16 | c.1030C>T p.L344= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100531287, COSV59121050; called by mutect2, varscan2
- SPATA21 | c.1089C>T p.P363= | Silent (SNP) | VAF 39/201 reads (19%) | catalogued as rs868255331, COSV100130785; called by muse, mutect2, varscan2
- SRCAP | c.5205A>T p.A1735= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as COSV99349795; called by muse, mutect2, varscan2
- STXBP5 | c.2292A>G p.L764= (on ENST00000321680 / NM_001127715.2; = p.L728= on NM_139244.4) | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV51654342; called by muse, mutect2
- ZG16B | c.471C>A p.P157= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV101206753; called by muse, mutect2, varscan2
- ZNF799 | c.1128T>C p.H376= | Silent (SNP) | VAF 56/197 reads (28%) | catalogued as rs748194148, COSV101345251; called by muse, mutect2, varscan2
- CPLANE1 | c.*5297T>C | 3'UTR (SNP) | VAF 36/142 reads (25%) | catalogued as COSV99950187, COSV99950287; called by muse, mutect2, varscan2
- DENND10P1 | n.473del | RNA (DEL) | VAF 53/124 reads (43%) | called by mutect2, pindel, varscan2
- FAM183BP | n.1315G>A | RNA (SNP) | VAF 42/257 reads (16%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1561G>T | RNA (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2, varscan2
- OR51S1 | c.-2C>A | 5'UTR (SNP) | VAF 12/80 reads (15%) | catalogued as COSV100437416; called by mutect2, varscan2
- OR52A4P | chr11:5121117 C>T | 3'Flank (SNP) | VAF 10/58 reads (17%) | called by muse, mutect2, varscan2
- PTGER3 | c.*24-12843C>G | Intron (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- UROC1 | c.903-607C>G | Intron (SNP) | VAF 24/83 reads (29%) | catalogued as COSV99331193; called by muse, mutect2, varscan2
